Gene-level copy-number profile of tumor specimen TCGA-C5-A1M6-01A from TCGA case TCGA-C5-A1M6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.0 years (20,090 days).
Specimen TCGA-C5-A1M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.0b30dfe8-e928-42d7-9fe7-982d328efdc2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1M6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/477e94bd-cbd2-4270-b875-805083137272

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,704; copy number 2: 27,062; copy number 3: 2,771; copy number 4: 18,183; copy number 5: 5,739; copy number 6: 4,109; copy number 7: 148; copy number 8: 19; copy number 14: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1M6-01A-11D-A13V-01): tumor purity 0.73, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,953 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–88,750,929, 1,523 genes, copy number 5 (broad region; genes not listed).
- chr3:90,202,316–198,222,513, 1,804 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr11:19,117,099–21,575,686, 28 genes, copy number 5–7 (within-gene range 4–7): ZDHHC13, CSRP3, CSRP3-AS1, E2F8, PCNAP4, AC009652.1, NAV2, NAV2-IT1, RNA5SP335, NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1, AC009549.1, MIR4694, NAV2-AS3, NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336.
- chr11:97,000,274–98,566,827, 8 genes, copy number 7: MED28P5, AP001836.1, LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1.
- chr12:43,835,967–51,515,763, 247 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:25,647,304–106,875,071, 1,806 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:3,100,696–3,143,734, 1 gene, copy number 6 (within-gene range 2–6): ZNF213-AS1.
- chr16:3,112,560–25,454,647, 593 genes, copy number 5–14 (broad region; genes not listed).
- chr16:25,824,710–25,826,330, 1 gene, copy number 5: AC093524.1.
- chr17:27,237,859–83,095,122, 2,113 genes, copy number 5 (broad region; genes not listed).
- chr18:8,133,203–8,155,070, 2 genes, copy number 6: AC006566.2, AC006566.1.
- chr19:19,978,190–21,427,577, 67 genes, copy number 5 (broad region; genes not listed).
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 4–5): SLC24A3.
- chr20:19,693,209–20,854,642, 19 genes, copy number 5: AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1.
- chr20:22,547,671–64,313,132, 1,030 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
